Somatic mutation profile of tumor specimen MP2PRT-PAWAEH-TMP1-A (aliquot MP2PRT-PAWAEH-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAWAEH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,960 days).
Specimen MP2PRT-PAWAEH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aef247b5-acca-4a14-b757-05747367bc7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAEH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAEH-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5fb48c5-584e-439b-a4dc-7cfc590a5ba7

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.10342G>A p.E3448K | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs368049814, CM1312809, COSV100243377; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- IL7R | c.728_731del p.L243Pfs*5 | Frame Shift Del (DEL) | VAF 49/199 reads (25%) | catalogued as COSV57413750, COSV99073410; called by pindel*, varscan2
- OPN1SW | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 134/369 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs767165831; called by muse, varscan2
- TMEM63C | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as rs551699396; called by muse, mutect2, varscan2
- ZNF516 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 224/574 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs1275218702; called by muse, mutect2, varscan2
- C20orf173 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 183/548 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CALCRL | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV3-66 | c.347_348insCCTAGAGGGGG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 25/85 reads (29%) | called by pindel, varscan2
- MAF | c.291C>G p.Y97* | Nonsense Mutation (SNP) | VAF 294/840 reads (35%) | called by muse, mutect2, varscan2
- STMN4 | c.548T>C p.L183P (on ENST00000265770 / NM_001283054.2; = p.L210P on NM_030795.4) | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- CNTNAP2 | c.1377C>T p.H459= | Silent (SNP) | VAF 111/301 reads (37%) | catalogued as rs377678020; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.9441C>T p.I3147= | Silent (SNP) | VAF 128/416 reads (31%) | catalogued as rs1402657419; called by muse, mutect2, varscan2
- PRR36 | c.1185G>A p.S395= | Silent (SNP) | VAF 159/468 reads (34%) | catalogued as rs1179941795; called by muse, mutect2, varscan2
- TLN2 | c.1467G>A p.P489= | Silent (SNP) | VAF 138/415 reads (33%) | catalogued as rs904541554; called by muse, mutect2, varscan2
- IGLV8-61 | chr22:22099212 ins CCT | 3'Flank (INS) | VAF 70/127 reads (55%) | called by mutect2, pindel, varscan2
